Somatic mutation profile of tumor specimen ALCH-B2SX-TTP1-A (aliquot ALCH-B2SX-TTP1-A-1-0-D-A77K-36) from ALCHEMIST case ALCH-B2SX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.2 years (24,908 days).
Specimen ALCH-B2SX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08430348-4c4b-4993-aed6-8de216da7613.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2SX-NB1-A (Blood Derived Normal), aliquot ALCH-B2SX-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e4ada86-36f1-4499-acb7-c1ce9848def2

The open-access MAF lists 1,127 somatic variants for this specimen: 810 protein-altering or splice-affecting, 193 silent, 124 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 715, Silent 193, Intron 50, Nonsense Mutation 49, RNA 32, Splice Site 22, 3'UTR 20, 5'UTR 14, Splice Region 10, Frame Shift Del 7, 5'Flank 4, 3'Flank 4.

Variants (750 of 1,127; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.526T>C p.C176R | Missense Mutation (SNP) | VAF 12/184 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967461896, CM165714, COSV52681947, COSV52682539, COSV52736779, COSV52752470; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ABCA13 | c.2767A>G p.I923V | Missense Mutation (SNP) | VAF 52/708 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs922856950, COSV70027093; called by muse, mutect2
- ABCA4 | c.2131A>T p.S711C | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs267598776; called by muse, mutect2
- ACE | c.3745G>T p.D1249Y | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV52004127; called by muse, mutect2
- ADAMTS12 | c.4188C>A p.D1396E | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as COSV61265622; called by muse, mutect2
- ADAMTS12 | c.2311G>T p.V771F | Missense Mutation (SNP) | VAF 28/588 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV61263194; called by muse, mutect2
- ADAMTS13 | c.3160G>A p.A1054T | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.328); catalogued as rs1554795152; called by muse, mutect2
- ADARB2 | c.1006C>A p.L336M | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67224423; called by muse, mutect2
- ADGRL3 | c.674C>A p.A225E (on ENST00000506720 / NM_001322402.2; = p.A157E on NM_015236.6) | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV72268675; called by muse, mutect2
- AFF2 | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV53974983, COSV54006254; called by muse, mutect2, varscan2
- ALOX5 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65553000; called by muse, mutect2
- AMN | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.82); catalogued as rs1209663083; called by muse, mutect2, varscan2
- ANK3 | c.1765G>T p.A589S | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55086348; called by muse, mutect2
- ANKRD33B | c.1048G>C p.A350P | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.095); catalogued as COSV56980454; called by muse, mutect2, varscan2
- AR | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.508); catalogued as rs1035114992, COSV65961009; called by muse, mutect2, varscan2
- ARHGAP9 | c.1217G>T p.R406L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57362424; called by muse, mutect2, varscan2
- ARHGEF10L | c.1489G>T p.A497S | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51439661; called by muse, mutect2
- ASL | c.1250+5G>A | Splice Region (SNP) | VAF 24/262 reads (9%) | catalogued as rs781201245; called by muse, mutect2
- ASTN1 | c.2548G>T p.D850Y | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV99921585; called by muse, mutect2
- ATP2C2 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.872); catalogued as rs557318842, COSV52300217; called by muse, mutect2, varscan2
- BDNF | c.446C>A p.T149K | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59234219; called by muse, mutect2
- BNC2 | c.655G>T p.G219* | Nonsense Mutation (SNP) | VAF 26/337 reads (8%) | catalogued as COSV66152892; called by muse, mutect2
- BOD1L1 | c.1742G>T p.R581M | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV50009804; called by muse, mutect2
- BTAF1 | c.1741G>T p.D581Y | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV99795094; called by muse, mutect2
- C16orf78 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV54557895; called by muse, mutect2
- C1QB | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 17/303 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV59245591; called by muse, mutect2
- C1orf105 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764594852; called by muse, mutect2, varscan2
- C8A | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 38/694 reads (5%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.521); catalogued as COSV100776479; called by muse, mutect2
- CACNA1S | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 61/428 reads (14%) | catalogued as rs565254185; called by muse, mutect2, varscan2
- CC2D2B | c.713C>A p.S238* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | catalogued as COSV60358212; called by muse, mutect2
- CCDC175 | c.2089G>C p.A697P | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as rs938324928; called by muse, mutect2, varscan2
- CCNE1 | c.181-2A>T p.X61_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | catalogued as COSV52903677; called by muse, mutect2
- CDH7 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as rs1269949009, COSV59898182; called by muse, mutect2, varscan2
- CDH9 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99142545, COSV99163558; called by muse, mutect2
- CDON | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 35/513 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.539); catalogued as rs1313305429; ClinVar: uncertain significance; called by muse, mutect2
- CELA2B | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as COSV65545579; called by mutect2, varscan2
- CFAP61 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs151062566; called by muse, mutect2
- CLASP1 | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV55335990; called by muse, mutect2
- CLIC5 | c.1115G>T p.G372V (on ENST00000185206 / NM_001370649.1; = p.G213V on NM_016929.5) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99484211; called by muse, mutect2, varscan2
- CLPB | c.1446G>C p.K482N | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV53633857; called by muse, mutect2
- CNDP1 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62593257; called by muse, mutect2
- CNTNAP5 | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101443679; called by muse, mutect2
- CNTNAP5 | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV70484940; called by muse, mutect2, varscan2
- COL11A2 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 30/498 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); catalogued as rs148765616, COSV59494377; called by muse, mutect2
- COL1A2 | c.3155C>T p.P1052L | Missense Mutation (SNP) | VAF 39/509 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1349537557; called by muse, mutect2
- CPN1 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 44/604 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs756808877; called by muse, mutect2
- CSMD1 | c.2574C>G p.I858M (on ENST00000520002; = p.I857M on NM_033225.6) | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.613); catalogued as COSV59353484; called by muse, mutect2
- CSMD3 | c.6880A>G p.I2294V (on ENST00000297405 / NM_001363185.1; = p.I2190V on NM_052900.3) | Missense Mutation (SNP) | VAF 58/460 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.173); catalogued as COSV52280231; called by muse, mutect2, varscan2
- CSMD3 | c.3142C>A p.L1048I (on ENST00000297405 / NM_001363185.1; = p.L944I on NM_052900.3) | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as rs1038971284, COSV52100311, COSV52199877, COSV52252257; called by muse, mutect2
- CYBB | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 38/274 reads (14%) | catalogued as CM012352; called by muse, mutect2, varscan2
- DCAF12L2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV63583722; called by muse, mutect2
- DCC | c.4084C>T p.P1362S | Missense Mutation (SNP) | VAF 34/845 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV71442625; called by muse, mutect2
- DENND1A | c.1839G>T p.R613S | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.816); catalogued as rs1471583738; called by muse, mutect2
- DGKB | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51765416; called by muse, mutect2
- DNAH3 | c.9487G>T p.E3163* | Nonsense Mutation (SNP) | VAF 14/302 reads (5%) | catalogued as rs1426230124; called by muse, mutect2
- DNAH8 | c.11360G>T p.G3787V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1472264977, COSV59470597; called by muse, mutect2
- DPYS | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs141867641; called by muse, mutect2
- DSCAML1 | c.1490C>A p.P497H (on ENST00000321322; = p.P437H on NM_020693.4) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58395718; called by muse, mutect2
- DTX3L | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1341616853; called by muse, mutect2
- DUS4L-BCAP29 | c.1683G>C p.L561F | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); catalogued as COSV50051093; called by muse, mutect2
- EFHD2 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1283627922; called by muse, mutect2
- EFS | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as rs779287241; called by muse, mutect2
- ENPEP | c.316G>T p.V106L | Missense Mutation (SNP) | VAF 27/538 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV54455144; called by muse, mutect2
- EPB41L3 | c.3113G>C p.R1038P | Missense Mutation (SNP) | VAF 36/474 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548087; called by muse, mutect2
- EPHA6 | c.631G>T p.V211F | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67562625; called by muse, mutect2
- ERBB4 | c.905G>C p.S302T | Missense Mutation (SNP) | VAF 26/510 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV53521687; called by muse, mutect2
- ERMN | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV68075474; called by muse, mutect2
- ESPL1 | c.5993A>T p.Y1998F | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99229277; called by muse, mutect2
- F13B | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); catalogued as COSV66372761, COSV66374131, COSV66374242; called by muse, mutect2
- FAIM2 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57738014; called by muse, mutect2
- FAM135B | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV99417615; called by muse, mutect2
- FAM47B | c.1820T>C p.I607T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as rs1306366787; called by mutect2, varscan2
- FAT2 | c.7343C>A p.S2448Y | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV55817036; called by muse, mutect2
- FIZ1 | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684622; called by muse, mutect2, varscan2
- FLNC | c.3367C>T p.P1123S | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290302048; called by muse, mutect2
- FLT4 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV56100986; called by muse, mutect2, varscan2
- FMR1 | c.1453G>C p.G485R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV99503317; called by muse, mutect2, varscan2
- FOXO1 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 17/283 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65429315; called by muse, mutect2
- FSIP2 | c.3731C>A p.P1244H | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV58086389; called by muse, mutect2
- FTMT | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV58420373, COSV58421761; called by muse, mutect2
- GABBR1 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.15); catalogued as rs755252386, COSV63543677; called by muse, mutect2
- GABRA4 | c.377A>T p.K126I | Missense Mutation (SNP) | VAF 13/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51930258; called by muse, mutect2
- GABRB1 | c.542G>C p.S181T | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54970265; called by muse, mutect2
- GABRQ | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100941430, COSV100941451; called by muse, mutect2, varscan2
- GBP5 | c.806C>G p.S269C | Missense Mutation (SNP) | VAF 21/315 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100599972; called by muse, mutect2
- GDPD4 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 17/314 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as rs1385264869, COSV60019106; called by muse, mutect2
- GPR85 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51783474, COSV51785882; called by muse, mutect2
- GRM7 | c.2005A>G p.S669G | Missense Mutation (SNP) | VAF 13/385 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100735883; called by muse, mutect2
- HCRTR2 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 36/506 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV63794614; called by muse, mutect2
- HMCN1 | c.6228C>A p.S2076R | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54874065; called by muse, mutect2
- HMCN1 | c.9265C>T p.P3089S | Missense Mutation (SNP) | VAF 37/744 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1295508594; called by muse, mutect2
- HNRNPCL1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 18/323 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58611880; called by muse, mutect2
- HOXA4 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100415578; called by muse, mutect2
- IGHD3-3 | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as rs546100128; called by muse, mutect2, varscan2
- IL1B | c.102C>A p.C34* | Nonsense Mutation (SNP) | VAF 21/302 reads (7%) | catalogued as COSV54521458; called by muse, mutect2
- ITGA4 | c.624+1G>T p.X208_splice | Splice Site (SNP) | VAF 3/29 reads (10%) | catalogued as COSV52004996; called by muse, mutect2
- ITLN1 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 17/311 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58276265; called by muse, mutect2
- KCNMA1 | c.2092+1G>T p.X698_splice | Splice Site (SNP) | VAF 18/312 reads (6%) | catalogued as COSV54240977; called by muse, mutect2
- KCNQ1 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as CM097819; called by muse, mutect2
- KCNT2 | c.2094A>T p.R698S | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs776727138, COSV54108167; called by muse, mutect2
- KDM7A | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99134032; called by muse, mutect2, varscan2
- KIAA0100 | c.6281C>T p.S2094L | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs756616185; called by muse, mutect2, varscan2
- KIF21A | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758156089, COSV62767435; called by muse, mutect2, varscan2
- KIF9 | c.2148G>T p.M716I (on ENST00000265529 / NM_001377474.1; = p.M651I on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55523158; called by muse, mutect2
- KIR2DL1 | c.949C>A p.R317S | Missense Mutation (SNP) | VAF 46/798 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV52412855; called by muse, mutect2
- KRT37 | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56659651; called by muse, mutect2
- KRT38 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); catalogued as rs190835091; called by muse, mutect2
- KRT4 | c.179G>A p.S60N | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1416524668, COSV53405858; called by muse, mutect2
- KRT78 | c.1036C>T p.L346F | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as rs868180219; called by muse, mutect2
- KRT83 | c.188C>A p.S63Y | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV53342463; called by muse, mutect2
- KRTAP4-4 | c.305G>C p.R102P | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV66811532; called by muse, mutect2
- LAMA1 | c.7427G>A p.G2476E | Missense Mutation (SNP) | VAF 34/404 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67531988; called by muse, mutect2
- LAMA2 | c.3854G>T p.R1285I | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.043); catalogued as COSV70352177; called by muse, mutect2
- LAMC2 | c.2318G>A p.S773N | Missense Mutation (SNP) | VAF 57/602 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs761794462; called by muse, mutect2
- LDB3 | c.228G>T p.L76F | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53945278; called by muse, mutect2
- LHCGR | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 44/598 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54294468; called by muse, mutect2
- LIG4 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 20/563 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV100799690; called by muse, mutect2
- LRP1B | c.10055G>T p.C3352F | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67253844; called by muse, mutect2
- MAGEC1 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.127); catalogued as rs200743510; called by muse, mutect2, varscan2
- MOV10 | c.257G>C p.R86P | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100659678; called by muse, mutect2
- MTDH | c.966G>T p.W322C | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60342929; called by muse, mutect2
- MUC12 | c.2926C>A p.P976T (on ENST00000379442; = p.P833T on NM_001164462.1) | Missense Mutation (SNP) | VAF 28/688 reads (4%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.65); catalogued as rs1355744209; called by muse, mutect2
- MUC16 | c.8056C>A p.L2686M | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV67493706; called by muse, mutect2
- MYH13 | c.805C>A p.L269M | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52837865, COSV99355305; called by muse, mutect2
- MYH13 | c.288C>A p.H96Q | Missense Mutation (SNP) | VAF 34/433 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs1356256540; called by muse, mutect2
- MYH7 | c.4363G>T p.E1455* | Nonsense Mutation (SNP) | VAF 29/267 reads (11%) | catalogued as CM102042, COSV62522034, COSV62522084; called by muse, mutect2, varscan2
- MYH8 | c.4946C>T p.T1649I | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs775934262; called by muse, mutect2
- MYOT | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53514648; called by muse, mutect2
- NBEAL2 | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as COSV99434332; called by muse, mutect2
- NCAM2 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53108379; called by muse, varscan2
- NCKAP1L | c.484C>A p.H162N | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV53207663; called by muse, varscan2
- NCL | c.1232A>C p.E411A | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as rs781232208; called by muse, mutect2
- NEK9 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 34/222 reads (15%) | catalogued as rs760861870; called by muse, mutect2, varscan2
- NEU4 | c.157C>A p.R53S (on ENST00000391969 / NM_001167602.3; = p.R65S on NM_080741.4) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.733); catalogued as COSV100372155; called by muse, mutect2
- NF2 | c.584A>C p.H195P | Missense Mutation (SNP) | VAF 24/470 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58524634; called by muse, mutect2
- NLRP3 | c.1625C>T p.T542M | Missense Mutation (SNP) | VAF 42/546 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs199856287, CM1413286, COSV60219661, COSV60221397; ClinVar: uncertain significance; called by muse, mutect2
- NRG3 | c.2069C>A p.A690D (on ENST00000404547 / NM_001370084.1; = p.A666D on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64541966; called by muse, mutect2
- NT5C1A | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180402827; called by muse, mutect2
- NUAK1 | c.1819T>C p.F607L | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54608803; called by muse, mutect2, varscan2
- NUP153 | c.2951G>T p.G984V | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50446786, COSV50459180; called by muse, mutect2
- NYAP2 | c.606G>T p.Q202H | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1266947731; called by muse, mutect2, varscan2
- OR10K2 | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100149624; called by muse, mutect2
- OR14K1 | c.584G>T p.S195I | Missense Mutation (SNP) | VAF 44/640 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99315126; called by muse, mutect2
- OR2C3 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 42/476 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs777675882, COSV63576489; called by muse, mutect2
- OR2V2 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs770132012, COSV60315037; called by mutect2, varscan2
- OR4A15 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.53); catalogued as rs1047332082; called by muse, mutect2
- OR4C11 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs150583796, COSV56352459; called by muse, mutect2
- OR5AS1 | c.545C>G p.P182R | Missense Mutation (SNP) | VAF 19/389 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100546189; called by muse, mutect2
- OR5J2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV56621099; called by muse, mutect2
- OR6K2 | c.710C>A p.T237K | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99080643; called by muse, mutect2
- OR8H1 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as rs762521957; called by muse, mutect2
- OSCAR | c.590A>T p.Y197F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV99500008; called by muse, mutect2, varscan2
- PADI1 | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778452294; called by muse, mutect2
- PASD1 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.047); catalogued as COSV64854514; called by muse, mutect2, varscan2
- PAX3 | c.874G>T p.G292W | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60589590; called by muse, mutect2
- PCDH11X | c.1321G>C p.A441P | Missense Mutation (SNP) | VAF 35/291 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100014769; called by muse, mutect2, varscan2
- PCDH15 | c.2395C>G p.R799G | Missense Mutation (SNP) | VAF 36/512 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57305930; called by muse, mutect2
- PCDH15 | c.908C>G p.P303R | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.774); catalogued as COSV57366774; called by muse, mutect2
- PCDHGA9 | c.1457G>T p.R486I | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV53896701; called by muse, mutect2
- PCDHGB4 | c.1658G>T p.R553L | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV54003159; called by muse, mutect2
- PCLO | c.6760G>A p.D2254N | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.109); catalogued as rs1402428469, COSV61646063; called by muse, mutect2, varscan2
- PEG3 | c.2987C>T p.P996L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs1309378250; called by muse, mutect2, varscan2
- PHF2 | c.1329+1G>T p.X443_splice | Splice Site (SNP) | VAF 7/95 reads (7%) | catalogued as COSV63683672; called by muse, mutect2
- PKHD1 | c.8555G>T p.G2852V | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100580825; called by muse, mutect2
- POTEG | c.228C>A p.S76R | Missense Mutation (SNP) | VAF 61/375 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV73630998, COSV73631080; called by muse, mutect2, varscan2
- PRIMA1 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.614); catalogued as COSV100301246; called by muse, mutect2
- PRPH | c.665T>C p.M222T | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.636); catalogued as rs1402620071; called by muse, mutect2
- PRR12 | c.607G>T p.A203S (on ENST00000615927; = p.A1024S on NM_020719.3) | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV101330734; called by muse, mutect2, varscan2
- PSG6 | c.537G>T p.W179C | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758821339; called by muse, mutect2
- PTPRD | c.4103A>T p.Q1368L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV61936210; called by muse, mutect2, varscan2
- PUDP | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV66904877; called by muse, mutect2, varscan2
- RAG1 | c.2752C>T p.R918C | Missense Mutation (SNP) | VAF 34/431 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs753962790; called by muse, mutect2
- RBMXL1 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 20/574 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); catalogued as COSV53103917; called by muse, mutect2
- RELN | c.7760C>A p.P2587Q | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1455056584; called by muse, mutect2
- RFPL4AL1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 18/502 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.098); catalogued as rs1312022920; called by muse, mutect2
- RNF148 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100411388; called by muse, mutect2
- RP1L1 | c.6217G>C p.E2073Q | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.793); catalogued as COSV66760814; called by muse, mutect2
- RP1L1 | c.5308C>A p.Q1770K | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as COSV66753394; called by muse, mutect2
- RPGRIP1 | c.3572G>T p.R1191L | Missense Mutation (SNP) | VAF 47/380 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52849250; called by muse, mutect2, varscan2
- RPS6KL1 | c.412C>G p.R138G | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV100665004; called by muse, mutect2
- RYR2 | c.5376A>G p.I1792M | Missense Mutation (SNP) | VAF 34/613 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV100772168; called by muse, mutect2
- SALL1 | c.2972C>A p.P991H | Missense Mutation (SNP) | VAF 78/1006 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as COSV51753413; called by muse, mutect2
- SCN2A | c.5545G>T p.G1849C | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99332338; called by muse, mutect2
- SEL1L3 | c.806G>T p.R269M | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.312); catalogued as COSV53537721; called by muse, mutect2
- SEMA5A | c.1249G>T p.V417F | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV66792721; called by muse, varscan2
- SENP7 | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV58611394, COSV58616474; called by muse, mutect2
- SLC26A4 | c.910G>T p.V304L | Missense Mutation (SNP) | VAF 33/388 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.035); catalogued as COSV55915556; called by muse, mutect2
- SLC26A4 | c.998G>T p.R333M | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV55917423; called by muse, mutect2
- SLC7A3 | c.1142G>T p.R381L | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV53226623; called by muse, mutect2, varscan2
- SLCO5A1 | c.2437G>A p.G813R | Missense Mutation (SNP) | VAF 16/361 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1322004591, COSV52657846; called by muse, mutect2
- SLFN12L | c.746G>T p.G249V (on ENST00000260908 / NM_001363830.1; = p.G267V on NM_001195790.1) | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104368470; called by muse, mutect2, varscan2
- SLITRK1 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV65677419; called by muse, mutect2
- SLITRK2 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs1382999990; called by muse, mutect2, varscan2
- SLPI | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100619797; called by muse, mutect2
- SNAI2 | c.424G>T p.G142W | Missense Mutation (SNP) | VAF 17/395 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99195031; called by muse, mutect2
- SOX17 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52023978; called by muse, mutect2, varscan2
- SPDYE1 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 37/568 reads (7%) | catalogued as rs758654901; called by muse, mutect2
- SPDYE4 | c.242G>T p.W81L | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60906225; called by muse, mutect2
- SPEF2 | c.2195del p.N732Tfs*53 | Frame Shift Del (DEL) | VAF 66/302 reads (22%) | catalogued as rs773088414; called by mutect2, pindel, varscan2
- SPOCK3 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.996); catalogued as COSV100694200, COSV62721436; called by muse, mutect2
- SPON1 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 14/202 reads (7%) | catalogued as COSV59961582; called by muse, mutect2
- SRGAP2 | c.3124C>T p.P1042S (on ENST00000624873 / NM_001170637.4; = p.P1043S on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as rs1454446917; called by muse, mutect2
- STARD6 | c.536T>A p.L179* | Nonsense Mutation (SNP) | VAF 6/93 reads (6%) | catalogued as COSV100323350; called by muse, mutect2
- STAT5B | c.1396G>T p.V466L | Missense Mutation (SNP) | VAF 42/412 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV53186979; called by muse, mutect2, varscan2
- SUN2 | c.2010C>A p.D670E | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99323625; called by muse, mutect2
- SYT14 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 61/440 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as rs1284270664; called by muse, mutect2, varscan2
- TAS2R41 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.875); catalogued as COSV68765677; called by muse, mutect2
- TEKT4 | c.1059C>A p.N353K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54623881, COSV54625292; called by muse, mutect2, varscan2
- TENM3 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 21/477 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101305499; called by muse, mutect2
- TET1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV101017609; called by muse, mutect2
- TG | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 23/303 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM127731; called by muse, mutect2
- TGFBRAP1 | c.461A>T p.Y154F | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV51513671; called by muse, mutect2
- TMCC3 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | catalogued as COSV54154139; called by muse, mutect2
- TMEM132A | c.1448G>T p.R483L (on ENST00000453848 / NM_178031.3; = p.R484L on NM_017870.4) | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.919); catalogued as COSV50019130; called by muse, mutect2
- TMEM132D | c.1189C>A p.Q397K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV70611677; called by muse, mutect2
- TMEM236 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 60/695 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1257332327; called by muse, mutect2
- TNFRSF8 | c.310C>A p.R104S | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55795454; called by muse, mutect2
- TOX | c.383G>C p.G128A | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV63846855; called by muse, mutect2
- TRAV10 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as rs1293935362; called by muse, mutect2
- TRIM17 | c.140C>A p.A47E | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs367605606, COSV54384334; called by muse, mutect2
- TRIM50 | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.021); catalogued as COSV100296775; called by muse, mutect2
- TRMT1L | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 23/313 reads (7%) | catalogued as rs1279036186; called by muse, mutect2
- TTBK1 | c.275G>T p.R92M | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52489110; called by muse, mutect2
- TYROBP | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.656); catalogued as rs903905038; called by muse, mutect2
- UBE3A | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as rs1194662343, COSV51670781; called by muse, mutect2
- UGT2B10 | c.543G>T p.R181S | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs781112661; called by muse, mutect2, varscan2
- USF2 | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55886046; called by muse, mutect2
- USH2A | c.9542G>T p.G3181V | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56406512; called by muse, mutect2
- USH2A | c.3706G>T p.V1236L | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.123); catalogued as COSV56405237; called by muse, mutect2
- VWDE | c.1975T>C p.S659P | Missense Mutation (SNP) | VAF 28/386 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1370937347; called by muse, mutect2
- WDR33 | c.2512G>T p.G838W | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1221209633; called by muse, mutect2
- WNT6 | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52110061; called by muse, mutect2, varscan2
- XIRP2 | c.6648C>A p.D2216E (on ENST00000628543; = p.D2391E on NM_152381.6) | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV54724344; called by muse, mutect2
- XKR7 | c.1178T>C p.L393P | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV101629289; called by muse, mutect2
- ZIC4 | c.394T>G p.W132G | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101268187; called by muse, mutect2
- ZMYM3 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV104405398; called by muse, mutect2, varscan2
- ZNF107 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs779305966; called by muse, mutect2, varscan2
- ZNF479 | c.1139C>A p.P380H | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58638177; called by muse, mutect2
- ZNF536 | c.2702G>T p.G901V | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV62818080; called by muse, mutect2
- ZNF600 | c.1971G>T p.R657S | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV57745250; called by muse, mutect2
- ZNF621 | c.524G>C p.G175A | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100182569, COSV59458606; called by muse, mutect2
- ZNF830 | c.938A>T p.E313V | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1336909868; called by muse, mutect2, varscan2
- ZNF845 | c.1754A>T p.H585L | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1467539700; called by muse, mutect2
- AADACL3 | c.283G>T p.G95W | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCC10 | c.304G>T p.V102L (on ENST00000372530 / NM_001198934.2; = p.V59L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- ABCC2 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- AC009093.9 | n.1077T>A | Splice Region (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- ACADSB | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 21/273 reads (8%) | called by muse, mutect2
- ACADSB | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); called by muse, mutect2
- ADAM29 | c.1863G>T p.L621F | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.119); called by muse, mutect2
- ADAMTS12 | c.1804A>T p.T602S | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.084); called by muse, mutect2
- ADAMTS9 | c.1309G>T p.G437C | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRB1 | c.1153T>A p.S385T | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.965); called by muse, mutect2
- ADGRG7 | c.1029T>A p.F343L | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- ADGRL4 | c.783T>A p.D261E | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.216); called by muse, mutect2
- AHCTF1 | c.2457G>T p.M819I (on ENST00000366508; = p.M793I on NM_015446.5) | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.187); called by muse, mutect2
- AHNAK | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 25/461 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); called by muse, mutect2
- AHNAK2 | c.7325T>A p.V2442E | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.969); called by muse, mutect2
- AKAP17A | c.404A>T p.K135M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by mutect2, varscan2
- ALG13 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ALG9 | c.1240G>T p.A414S (on ENST00000614444 / NM_001352418.1; = p.A421S on NM_024740.2) | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2
- ALK | c.1298C>A p.S433Y | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); called by muse, mutect2
- ALMS1 | c.7554G>T p.K2518N | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ALPI | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- AMMECR1L | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ANGPTL5 | c.409C>G p.P137A | Missense Mutation (SNP) | VAF 29/506 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- ANHX | c.50C>G p.P17R | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2
- ANK1 | c.4411C>A p.L1471M | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APOB | c.3019C>G p.P1007A | Missense Mutation (SNP) | VAF 22/509 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- APOB | c.3018G>T p.R1006S | Missense Mutation (SNP) | VAF 20/511 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2
- ARAP1 | c.3694G>A p.E1232K (on ENST00000393609 / NM_001040118.2; = p.E987K on NM_015242.4) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARHGAP5 | c.2911G>T p.D971Y | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- ARID1A | c.3198+1G>A p.X1066_splice | Splice Site (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- ARMC3 | c.376C>A p.H126N | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2
- ASB2 | c.1240G>T p.D414Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ASXL3 | c.1817C>A p.A606D | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATP13A4 | c.1082C>G p.S361C | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2
- ATP6V1H | c.1176-2A>G p.X392_splice | Splice Site (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- ATRX | c.6417G>T p.W2139C | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATRX | c.6416G>T p.W2139L | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AVPR1B | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- B4GALNT3 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2
- BAK1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 18/185 reads (10%) | called by muse, mutect2
- BARHL1 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- BBS9 | c.1612G>T p.G538C (on ENST00000242067 / NM_001348036.1; = p.G498C on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/533 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- BCOR | c.3295G>C p.D1099H | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- BCR | c.1773C>G p.Y591* | Nonsense Mutation (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- BIRC6 | c.12913G>T p.D4305Y | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BMPR1A | c.523T>C p.C175R | Missense Mutation (SNP) | VAF 21/427 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2
- BOD1L1 | c.3803G>A p.G1268E | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2
- BOD1L1 | c.887A>G p.E296G | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- BTN2A2 | c.1032G>C p.E344D | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.125); called by muse, mutect2
- BZW1 | c.649-1G>T p.X217_splice | Splice Site (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- BZW1 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- C10orf82 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.287); called by muse, mutect2
- C19orf38 | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.359); called by muse, mutect2
- C20orf85 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); called by muse, mutect2
- C2orf78 | c.2671G>T p.E891* | Nonsense Mutation (SNP) | VAF 20/298 reads (7%) | called by muse, mutect2
- C3orf38 | c.211A>T p.I71L | Missense Mutation (SNP) | VAF 20/367 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.102); called by muse, mutect2
- C3orf38 | c.213A>G p.I71M | Missense Mutation (SNP) | VAF 20/377 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- C7 | c.868A>T p.S290C | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- C7orf31 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- CA2 | c.731G>T p.W244L | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.19); called by muse, mutect2
- CACNA2D1 | c.2796G>T p.W932C (on ENST00000356253 / NM_001366867.1; = p.W920C on NM_000722.4) | Missense Mutation (SNP) | VAF 26/493 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CALCRL | c.518G>T p.R173M | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAMKMT | c.971A>G p.*324Wext*25 | Nonstop Mutation (SNP) | VAF 9/232 reads (4%) | called by muse, mutect2
- CBX2 | c.505del p.L169Cfs*12 | Frame Shift Del (DEL) | VAF 32/334 reads (10%) | called by mutect2, pindel
- CCDC136 | c.1279C>A p.L427I | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2
- CCDC151 | c.1343C>A p.A448D | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- CCDC191 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 17/273 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- CCN4 | c.1065C>A p.D355E | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.583); called by muse, mutect2
- CCSER1 | c.2625G>T p.M875I | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, mutect2
- CD109 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 13/325 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- CD163 | c.1772C>A p.P591Q | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2
- CD177 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- CD300C | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC14C | c.1573C>A p.P525T (on ENST00000428251; = p.P418T on NM_152627.3) | Missense Mutation (SNP) | VAF 27/627 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2
- CDC73 | c.1300C>G p.L434V | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- CDH12 | c.348C>A p.S116R | Missense Mutation (SNP) | VAF 59/332 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CDH12 | c.97A>C p.T33P | Missense Mutation (SNP) | VAF 56/373 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CDH17 | c.634T>A p.S212T | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.493); called by muse, mutect2
- CDR1 | c.47dup p.L16Ffs*24 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, varscan2
- CDX2 | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- CEP112 | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- CEP131 | c.2128G>T p.G710C (on ENST00000269392 / NM_001319228.2; = p.G707C on NM_014984.4) | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CEP295NL | c.1572A>C p.E524D | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.278); called by muse, mutect2
- CEP63 | c.978G>T p.Q326H | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2
- CFAP206 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 16/371 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2
- CFAP69 | c.2492T>A p.L831Q | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.074); called by muse, mutect2
- CFAP99 | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.09); called by muse, mutect2
- CFHR4 | c.1202A>T p.E401V (on ENST00000367416 / NM_001201551.2; = p.E155V on NM_006684.5) | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.224); called by muse, mutect2
- CHD5 | c.5231T>A p.L1744Q | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- CHIT1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 16/411 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHMP2B | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.206); called by muse, mutect2
- CHRFAM7A | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNKSR2 | c.601dup p.L201Pfs*22 | Frame Shift Ins (INS) | VAF 21/142 reads (15%) | called by mutect2, pindel, varscan2
- CNTNAP4 | c.1462G>T p.G488C | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- COL11A1 | c.4529G>C p.G1510A | Missense Mutation (SNP) | VAF 24/605 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL14A1 | c.4000G>T p.D1334Y | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL19A1 | c.370A>T p.N124Y | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- COL1A1 | c.2102G>T p.G701V | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL21A1 | c.2026C>A p.P676T | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.062); called by muse, mutect2
- COL5A2 | c.1141G>T p.G381* | Nonsense Mutation (SNP) | VAF 43/588 reads (7%) | called by muse, mutect2
- COL6A5 | c.5005C>A p.P1669T | Missense Mutation (SNP) | VAF 29/340 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.164); called by muse, mutect2
- COL6A6 | c.3592G>T p.E1198* | Nonsense Mutation (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- CPA3 | c.900C>A p.Y300* | Nonsense Mutation (SNP) | VAF 24/456 reads (5%) | called by muse, mutect2
- CREB3L2 | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 28/293 reads (10%) | called by muse, mutect2
- CRIM1 | c.1081G>C p.G361R | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CRYBG3 | c.3781G>T p.G1261C | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- CRYM | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 18/369 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD1 | c.993C>A p.S331R | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2
- CSMD3 | c.7540G>T p.V2514L (on ENST00000297405 / NM_001363185.1; = p.V2410L on NM_052900.3) | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2
- CSMD3 | c.4151del p.G1384Afs*13 (on ENST00000297405 / NM_001363185.1; = p.G1280Afs*13 on NM_052900.3) | Frame Shift Del (DEL) | VAF 30/220 reads (14%) | called by mutect2, varscan2
- CTCFL | c.1865C>A p.T622N | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- CTNNA2 | c.2245G>T p.A749S | Missense Mutation (SNP) | VAF 21/387 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.23); called by muse, mutect2
- CUX1 | c.2464G>T p.D822Y | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CYRIA | c.870G>T p.Q290H | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2
- CYTH1 | c.1145A>T p.Y382F | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- DACH1 | c.1981A>T p.R661W (on ENST00000619232 / NM_001366712.1; = p.R407W on NM_004392.6) | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- DACT1 | c.1740G>T p.K580N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- DCAF4L2 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- DDX28 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- DEF8 | c.251G>T p.G84V (on ENST00000268676 / NM_207514.3; = p.G23V on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2
- DERA | c.130-1G>T p.X44_splice | Splice Site (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- DGKI | c.2982G>T p.T994= | Splice Region (SNP) | VAF 19/173 reads (11%) | called by muse, mutect2, varscan2
- DIP2C | c.1517G>A p.S506N | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- DKK2 | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- DLGAP2 | c.1134G>T p.Q378H | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); called by muse, mutect2
- DMP1 | c.818T>G p.I273S | Missense Mutation (SNP) | VAF 42/904 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DMRT2 | c.572C>A p.A191D | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.321); called by muse, mutect2
- DNAH3 | c.9239T>C p.L3080S | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH3 | c.4951G>T p.G1651* | Nonsense Mutation (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- DNAH5 | c.5729G>T p.S1910I | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- DNAH7 | c.2902G>T p.G968C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- DNER | c.1319A>T p.Q440L | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2
- DOCK11 | c.5807_5821del p.T1936_M1940del | In Frame Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel
- DPEP3 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- DPH7 | c.744C>G p.S248R | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DRD2 | c.1115C>T p.T372I | Missense Mutation (SNP) | VAF 15/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DYDC2 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2
- DYDC2 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 27/323 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2
- EBF3 | c.493T>C p.C165R | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2
- EFCAB8 | c.3335G>T p.R1112L | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- EFHB | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- EHMT2 | c.3112G>C p.V1038L | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- ELAPOR2 | c.1399G>T p.G467C (on ENST00000450689 / NM_001142749.3; = p.G300C on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ENDOV | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ERICH3 | c.1203G>T p.M401I | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- ETS1 | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- ETV3L | c.106T>A p.S36T | Missense Mutation (SNP) | VAF 10/251 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- EVPL | c.1537+8G>T | Splice Region (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- FAM102B | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.298); called by muse, mutect2
- FAM133A | c.136A>G p.K46E | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- FAM184B | c.2630C>A p.A877D | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FAM214A | c.1023G>T p.M341I | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- FAM47A | c.1844C>A p.A615D | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- FAM83B | c.1799C>A p.P600H | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2
- FAM83H | c.2999G>T p.R1000L | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- FAT3 | c.2543C>G p.T848S | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.371); called by muse, mutect2
- FBXO31 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.335); called by muse, mutect2
- FBXO43 | c.1409G>T p.G470V | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2
- FCGRT | c.1065G>T p.L355F | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- FDXR | c.1403G>T p.R468L (on ENST00000293195 / NM_024417.5; = p.R474L on NM_004110.6) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FFAR4 | c.896C>A p.T299N | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2
- FGA | c.1459G>T p.D487Y | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FLG2 | c.2402C>A p.S801* | Nonsense Mutation (SNP) | VAF 38/535 reads (7%) | called by muse, mutect2
- FOXRED1 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); called by muse, mutect2
- FPR1 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FSIP2 | c.8531G>T p.W2844L | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- FTMT | c.406C>G p.R136G | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- GABRB1 | c.1022C>A p.A341D | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2
- GABRG3 | c.1381T>A p.W461R | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GADL1 | c.1458C>A p.H486Q | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2
- GARNL3 | c.2923G>T p.G975W | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.425); called by muse, mutect2
- GATAD2B | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GCC1 | c.1466A>T p.K489M | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- GDF10 | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GDPD4 | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); called by muse, mutect2
- GGA2 | c.1336G>T p.G446C | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- GIMAP6 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GLG1 | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLRA2 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GLRA4 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GNPTAB | c.610A>T p.R204* | Nonsense Mutation (SNP) | VAF 26/385 reads (7%) | called by muse, mutect2
- GOT1L1 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GPC6 | c.1335C>A p.N445K | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- GPD2 | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- GPR179 | c.2317C>G p.R773G (on ENST00000621958; = p.R772G on NM_001004334.4) | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.214); called by muse, mutect2
- GPR50 | c.1096_1097delinsA p.N367Mfs*226 | Frame Shift Del (DEL) | VAF 26/142 reads (18%) | called by pindel, varscan2*
- GPR65 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 32/329 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GPRC5B | c.615C>G p.I205M | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2
- GRID1 | c.965A>G p.Y322C | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRID2 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 9/276 reads (3%) | SIFT tolerated (0.97); PolyPhen benign (0.098); called by muse, mutect2
- GRIN1 | c.529C>G p.Q177E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- GRIN2A | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- GRIN3A | c.597C>A p.F199L | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); called by muse, mutect2
- GRN | c.772A>T p.S258C | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- GSG1L | c.831G>A p.R277= (on ENST00000447459 / NM_001109763.2; = p.R122= on NM_144675.2) | Splice Region (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- GTSF1 | c.410T>A p.V137D | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- HACE1 | c.2594A>G p.Y865C | Missense Mutation (SNP) | VAF 11/406 reads (3%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.866); called by muse, mutect2
- HAO1 | c.425A>T p.K142M | Missense Mutation (SNP) | VAF 37/540 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.279); called by muse, mutect2
- HAP1 | c.1284G>T p.W428C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.75); called by muse, mutect2
- HEATR1 | c.5592G>T p.Q1864H | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- HEMGN | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 13/199 reads (7%) | called by muse, mutect2
- HHIPL2 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.029); called by muse, mutect2
- HIVEP2 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.235); called by muse, mutect2
- HMGCS2 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 16/415 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.098); called by muse, mutect2
- HNRNPA1 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- HOXA10 | c.910C>A p.P304T | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.386); called by muse, mutect2
- HOXA13 | c.1136A>T p.K379I | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HOXB3 | c.224G>T p.R75M | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- HOXC10 | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); called by muse, mutect2
- HPSE2 | c.733T>A p.L245M | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2
- HRH2 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- HSD17B6 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HTR4 | c.717G>T p.R239S | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HTR7 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HYDIN | c.6191G>T p.C2064F | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2
- HYOU1 | c.2688G>A p.M896I | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- IFI16 | c.742A>T p.S248C | Missense Mutation (SNP) | VAF 45/479 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2
- IFNA16 | c.377A>T p.E126V | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.949); called by muse, mutect2
- IFT140 | c.3652A>G p.K1218E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2
- IGF2BP2 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGHD3-22 | c.11G>T p.*4Lext*? | Nonstop Mutation (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- IGHV1-2 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 71/547 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- IGLC7 | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2
- IL16 | c.3230C>A p.S1077Y (on ENST00000302987 / NM_172217.5; = p.S376Y on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/315 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2
- INPP4B | c.2237T>C p.F746S | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- INSC | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- IQGAP2 | c.4305T>A p.Y1435* | Nonsense Mutation (SNP) | VAF 24/318 reads (8%) | called by muse, mutect2
- ITGBL1 | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ITIH3 | c.2524C>T p.H842Y | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.393); called by muse, mutect2
- ITIH6 | c.3811C>A p.P1271T | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- ITPRID1 | c.305T>A p.M102K | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2
- JPT2 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.156); called by muse, mutect2
- KALRN | c.2969A>T p.Q990L | Missense Mutation (SNP) | VAF 13/402 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- KANK1 | c.1448G>T p.R483L | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- KAT6B | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- KCNH8 | c.2615G>T p.S872I | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, mutect2
- KCNT2 | c.3283C>A p.L1095M | Missense Mutation (SNP) | VAF 22/371 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); called by muse, mutect2
- KDM4E | c.691A>T p.I231F | Missense Mutation (SNP) | VAF 31/417 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2
- KDM5C | c.3707G>T p.W1236L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- KIF19 | c.2218G>T p.E740* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2
- KIR3DL2 | c.350T>A p.V117D | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- KLHL15 | c.1228G>T p.D410Y | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KMT2B | c.2154G>T p.E718D | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.549); called by muse, mutect2
- KNG1 | c.1489C>A p.H497N | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.109); called by muse, mutect2
- KRT27 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- KRT37 | c.284A>T p.Y95F | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2
- KRT38 | c.235T>A p.L79M | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); called by muse, varscan2
- KRT73 | c.135T>A p.S45R | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- KRTAP29-1 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 46/396 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LBR | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 41/538 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LCP1 | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- LHFPL3 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- LPIN1 | c.2100G>T p.W700C | Missense Mutation (SNP) | VAF 57/449 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRFN1 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRP1B | c.13658G>T p.G4553V | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- LRP1B | c.12050A>C p.N4017T | Missense Mutation (SNP) | VAF 62/577 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.575); called by muse, mutect2
- LRP1B | c.6898C>A p.Q2300K | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); called by muse, mutect2
- LRP5 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.6); called by muse, mutect2
- LUZP2 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LYZL1 | c.458C>A p.T153K (on ENST00000375500; = p.T107K on NM_032517.6) | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- LZTS3 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2
- MADD | c.3505T>C p.S1169P | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- MAGEA6 | c.298del p.D100Tfs*50 | Frame Shift Del (DEL) | VAF 30/173 reads (17%) | called by mutect2, varscan2
- MAP3K10 | c.1585G>T p.G529C | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.286); called by muse, mutect2
- MAP3K20 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- MARK1 | c.1148G>A p.S383N | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAS1 | c.772T>A p.F258I | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.124); called by muse, mutect2
- MAS1L | c.958C>T p.L320F | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MAT1A | c.979C>A p.P327T | Missense Mutation (SNP) | VAF 39/482 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MATN2 | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MC5R | c.161A>T p.N54I | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MCF2L2 | c.2338A>T p.I780L | Missense Mutation (SNP) | VAF 26/441 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- MDGA2 | c.1061del p.P354Lfs*6 (on ENST00000399232 / NM_001113498.2; = p.P56Lfs*6 on NM_182830.4) | Frame Shift Del (DEL) | VAF 62/544 reads (11%) | called by mutect2, pindel, varscan2
- MED12 | c.2712G>T p.E904D | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MERTK | c.2432A>T p.D811V | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MET | c.1831A>T p.T611S | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.174); called by muse, mutect2
- MFSD9 | c.460G>C p.A154P | Missense Mutation (SNP) | VAF 23/385 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- MGAM2 | c.5875G>C p.D1959H | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated, low confidence (0.13); called by muse, mutect2
- MGAT3 | c.1557G>T p.E519D | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAT5B | c.2351A>T p.Q784L (on ENST00000569840 / NM_001199172.2; = p.Q782L on NM_144677.3) | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- MICB | c.678G>T p.R226S | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.372); called by muse, mutect2
- MLC1 | c.681C>A p.H227Q | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MON1B | c.614G>T p.S205I | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- MON2 | c.2365-1G>T p.X789_splice | Splice Site (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- MOV10L1 | c.696G>T p.Q232H | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- MPP2 | c.914G>T p.G305V (on ENST00000461854 / NM_001278372.2; = p.G281V on NM_005374.5) | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPP3 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MROH2A | c.3655G>T p.A1219S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); called by muse, mutect2
- MROH5 | c.3032C>A p.P1011Q | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0.006); called by muse, mutect2
- MRPL1 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- MS4A8 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.253); called by muse, mutect2
- MTNR1A | c.897C>A p.N299K | Missense Mutation (SNP) | VAF 25/611 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUC16 | c.35372T>C p.V11791A | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2
- MUC16 | c.2483C>A p.T828N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); called by muse, mutect2
- MXRA5 | c.7723G>A p.V2575M | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- MYH11 | c.5419G>A p.A1807T | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2
- MYH2 | c.5590A>T p.R1864* | Nonsense Mutation (SNP) | VAF 44/514 reads (9%) | called by muse, mutect2
- MYL7 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.26); called by muse, mutect2
- MYO9A | c.2106G>T p.W702C | Missense Mutation (SNP) | VAF 14/381 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYOCD | c.1075G>T p.V359F | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- MYPN | c.2824T>A p.C942S | Missense Mutation (SNP) | VAF 31/382 reads (8%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.556); called by muse, mutect2
- NBAS | c.6031G>T p.D2011Y | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2
- NBAS | c.5191A>T p.T1731S | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- NBAS | c.647G>T p.S216I | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- NCKAP5L | c.3123G>T p.K1041N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.255); called by muse, mutect2
- NCR2 | c.245C>G p.T82R | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2
- NDST4 | c.2115G>T p.Q705H | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- NDST4 | c.985C>A p.L329I | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.277); called by muse, mutect2
- NDUFAF6 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- NDUFAF7 | c.671A>T p.H224L | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NEK3 | c.763G>T p.G255C | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by muse, mutect2
- NHLRC3 | c.899G>T p.S300I | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2
- NLRP1 | c.1191G>T p.Q397H | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NLRP14 | c.2292-1G>T p.X764_splice | Splice Site (SNP) | VAF 28/438 reads (6%) | called by muse, mutect2
- NLRP3 | c.1980C>A p.D660E | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.751); called by muse, mutect2
- NOS2 | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOTCH3 | c.688G>T p.G230C | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NRG3 | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.801); called by muse, mutect2
- NRXN1 | c.3892G>T p.G1298C | Missense Mutation (SNP) | VAF 18/309 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- NSL1 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NSUN2 | c.1206G>T p.Q402H | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NTRK1 | c.2366C>A p.P789H | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NXPE2 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- OAS2 | c.1385C>A p.P462H | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OBSL1 | c.5371C>A p.Q1791K | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.428); called by muse, mutect2
- OGFR | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- OLFM1 | c.425G>A p.S142N (on ENST00000371793 / NM_001282611.2; = p.S124N on NM_006334.4) | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- OR10C1 | c.920A>T p.Q307L (on ENST00000622521; = p.Q305L on NM_013941.3) | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2
- OR10Z1 | c.470T>A p.L157Q | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.824); called by muse, mutect2
- OR14K1 | c.491T>A p.L164Q | Missense Mutation (SNP) | VAF 34/367 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- OR1M1 | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR1S1 | c.699C>A p.C233* | Nonsense Mutation (SNP) | VAF 26/490 reads (5%) | called by muse, mutect2
- OR2A5 | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 24/270 reads (9%) | called by muse, mutect2
- OR2AG1 | c.291T>A p.C97* | Nonsense Mutation (SNP) | VAF 14/305 reads (5%) | called by muse, mutect2
- OR2L5 | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR2L5 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- OR2M3 | c.487A>T p.T163S | Missense Mutation (SNP) | VAF 26/343 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.232); called by muse, mutect2
- OR2T10 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2T27 | c.719C>G p.T240S | Missense Mutation (SNP) | VAF 40/362 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- OR4D11 | c.485T>G p.L162R | Missense Mutation (SNP) | VAF 24/381 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR4K17 | c.865C>G p.L289V | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2
- OR4L1 | c.152G>T p.C51F | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2
- OR51E1 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- OR51L1 | c.136A>T p.T46S | Missense Mutation (SNP) | VAF 11/300 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- OR5AK2 | c.598G>C p.V200L | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2
- OR5AP2 | c.369G>T p.M123I | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- OR5AS1 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 19/387 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- OR5H6 | c.331T>A p.S111T (on ENST00000642105; = p.S95T on NM_001005479.2) | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.033); called by muse, varscan2
- OR5M8 | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.075); called by muse, mutect2
- OR6N2 | c.839T>A p.V280E | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OR7G2 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.06); called by muse, mutect2
- OR9A2 | c.25A>T p.T9S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by mutect2, varscan2
- OXCT1 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- PABPN1L | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.615); called by muse, mutect2
- PAK6 | c.-5-1G>T | Splice Site (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- PALM2AKAP2 | c.1467G>T p.E489D (on ENST00000259318 / NM_001136562.3; = p.E720D on NM_007203.5) | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2
- PAPOLA | c.583A>T p.I195L | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.267); called by muse, varscan2
- PAQR9 | c.404T>C p.M135T | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2
- PARP1 | c.459G>T p.M153I | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.039); called by muse, mutect2
- PATL1 | c.1774A>C p.K592Q | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PCDH10 | c.1337G>T p.S446I | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); called by muse, mutect2
- PCDH15 | c.4919A>T p.K1640M (on ENST00000644397 / NM_001354429.2; = p.K1582M on NM_001142771.2) | Missense Mutation (SNP) | VAF 36/524 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- PCDH15 | c.2974G>C p.V992L | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); called by muse, mutect2
- PCDH15 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 29/592 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH17 | c.779C>A p.T260K | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.042); called by muse, mutect2
- PCDHA3 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PCDHB6 | c.728A>T p.Q243L | Missense Mutation (SNP) | VAF 25/377 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2
- PCDHB6 | c.1727G>T p.R576L | Missense Mutation (SNP) | VAF 19/412 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2
- PCDHB8 | c.2087C>A p.A696D | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- PCLO | c.11573C>T p.T3858I | Missense Mutation (SNP) | VAF 19/469 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCOLCE2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2
- PDE1A | c.978G>C p.M326I | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.3); called by muse, mutect2
- PDGFRB | c.785C>G p.T262S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- PDGFRB | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- PDP1 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 36/662 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- PEAK1 | c.4741A>T p.I1581F | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- PFKL | c.638+1G>A p.X213_splice | Splice Site (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2, varscan2
- PGBD1 | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.372); called by muse, mutect2
- PHACTR3 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 21/259 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- PIEZO2 | c.3505T>A p.Y1169N | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PIP5K1A | c.877G>T p.G293C (on ENST00000368888 / NM_001135638.2; = p.G280C on NM_003557.3) | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PKHD1L1 | c.3415G>A p.G1139R | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- PLAAT5 | c.199G>C p.A67P | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.446); called by muse, mutect2
- PLCE1 | c.2821G>T p.V941L | Missense Mutation (SNP) | VAF 27/435 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- PLEKHB2 | c.545A>T p.Q182L (on ENST00000409279; = p.Q181L on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PLG | c.430T>A p.S144T | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2
- PLXNC1 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 13/314 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.18); called by muse, mutect2
- POLRMT | c.1547G>T p.R516M | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.101); called by muse, mutect2
- POU2F2 | c.659C>A p.T220K (on ENST00000526816 / NM_001207025.3; = p.T204K on NM_002698.5) | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- POU5F1B | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 27/438 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- PPP1R2B | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 44/642 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.017); called by muse, mutect2
- PPP1R3A | c.112T>G p.S38A | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- PPP1R9A | c.2274G>T p.Q758H | Missense Mutation (SNP) | VAF 17/326 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- PPP4R3C | c.1657C>A p.L553M | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRAMEF1 | c.441A>T p.L147F | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRAMEF7 | c.1322G>A p.R441K | Missense Mutation (SNP) | VAF 38/742 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.065); called by muse, mutect2
- PRKDC | c.8850G>T p.K2950N | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2
- PRKG1 | c.762+3A>T | Splice Region (SNP) | VAF 25/202 reads (12%) | called by muse, mutect2, varscan2
- PRPF4B | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 33/367 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.436); called by muse, mutect2
- PRR15 | c.97_98insACGC p.P33Hfs*67 | Frame Shift Ins (INS) | VAF 8/85 reads (9%) | called by mutect2, pindel
- PRR35 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by mutect2, varscan2
- PRRC2C | c.6252A>T p.E2084D (on ENST00000367742; = p.E2082D on NM_015172.4) | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PRSS21 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.112); called by muse, mutect2
- PSG6 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.189); called by muse, mutect2
- PSG7 | c.556A>G p.S186G | Missense Mutation (SNP) | VAF 32/568 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2
- PSG7 | c.34C>A p.H12N | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.131); called by muse, mutect2
- PTCHD4 | c.253C>A p.R85S | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.489); called by muse, mutect2
- PTGS1 | c.673C>A p.H225N | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.746); called by muse, mutect2
- PTPN14 | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- PTPRB | c.3832G>T p.A1278S | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.05); called by muse, mutect2
- PTPRZ1 | c.3382A>G p.T1128A | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PYDC2 | c.188C>A p.S63Y | Missense Mutation (SNP) | VAF 24/359 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); called by muse, mutect2
- RAG1 | c.2371G>T p.V791F | Missense Mutation (SNP) | VAF 18/440 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2
- RANBP2 | c.5329G>T p.G1777* | Nonsense Mutation (SNP) | VAF 24/351 reads (7%) | called by muse, mutect2
- RAPGEF2 | c.253A>G p.K85E | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); called by muse, mutect2
- RAPGEF2 | c.193-1G>T p.X65_splice | Splice Site (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- RASAL3 | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- RASGRF1 | c.3660+1G>A p.X1220_splice | Splice Site (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- RB1CC1 | c.3043G>T p.E1015* | Nonsense Mutation (SNP) | VAF 24/348 reads (7%) | called by muse, mutect2
- REG1A | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 29/433 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- REPIN1 | c.637G>T p.G213W | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- RFX8 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- RGS18 | c.604A>T p.M202L | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- RNF165 | c.203T>A p.M68K | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2
- RNF31 | c.2477dup p.R827Afs*16 | Frame Shift Ins (INS) | VAF 23/164 reads (14%) | called by mutect2, pindel, varscan2
- RPGR | c.1059G>T p.L353F | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, varscan2
- RSL1D1 | c.1324A>T p.K442* | Nonsense Mutation (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- RYR1 | c.1441-2A>T p.X481_splice | Splice Site (SNP) | VAF 29/358 reads (8%) | called by muse, mutect2
- RYR1 | c.5983A>G p.T1995A | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- S1PR4 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- SACS | c.4000A>T p.M1334L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SACS | c.1459G>T p.D487Y | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SAMD11 | c.658G>C p.G220R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by mutect2, varscan2
- SAMD13 | c.307A>T p.K103* (on ENST00000370671; = p.K97* on NM_001010971.3) | Nonsense Mutation (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- SCAF11 | c.4294C>G p.L1432V | Missense Mutation (SNP) | VAF 13/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SCN11A | c.2022G>A p.V674= | Splice Region (SNP) | VAF 8/71 reads (11%) | called by mutect2, varscan2
- SCN3A | c.3394-2A>G p.X1132_splice | Splice Site (SNP) | VAF 57/534 reads (11%) | called by muse, mutect2, varscan2
- SCN7A | c.4600G>T p.D1534Y | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SEC24D | c.2560G>T p.V854L | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.408); called by muse, mutect2
- SEC31B | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SEC31B | c.1204G>T p.G402C | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- SENP6 | c.797A>T p.Q266L | Missense Mutation (SNP) | VAF 23/460 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.001); called by muse, mutect2
- SEPTIN14 | c.1071G>T p.M357I | Missense Mutation (SNP) | VAF 14/337 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2
- SEPTIN14 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEZ6L2 | c.2563T>A p.L855M (on ENST00000308713 / NM_001114099.3; = p.L798M on NM_012410.4) | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- SH3PXD2B | c.1252G>T p.E418* (on ENST00000636523; = p.E404* on NM_001308175.1) | Nonsense Mutation (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- SH3PXD2B | c.1251G>T p.L417F (on ENST00000636523; = p.L403F on NM_001308175.1) | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); called by muse, mutect2
- SHANK2 | c.2061+1G>T p.X687_splice | Splice Site (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- SHANK2 | c.2061G>T p.E687D | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- SHOX2 | c.649T>A p.C217S (on ENST00000441443 / NM_006884.3; = p.C241S on NM_003030.4) | Missense Mutation (SNP) | VAF 28/365 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SHROOM2 | c.4469T>A p.M1490K | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SIGLEC12 | c.938C>A p.S313Y (on ENST00000291707 / NM_053003.4; = p.S195Y on NM_033329.2) | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- SKA3 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- SLAMF1 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC22A12 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2
- SLC25A28 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 25/252 reads (10%) | called by muse, mutect2, varscan2
- SLC35G3 | c.929T>C p.I310T | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC4A10 | c.2953C>T p.L985F (on ENST00000446997 / NM_001354461.2; = p.L955F on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLCO1C1 | c.839T>C p.I280T | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2
- SLITRK2 | c.653G>T p.W218L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMCHD1 | c.5182C>T p.H1728Y | Missense Mutation (SNP) | VAF 31/391 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SMPX | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SNTG1 | c.1093G>T p.G365W | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SORCS3 | c.2197G>T p.G733C | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- SPACA9 | c.256G>T p.V86L | Missense Mutation (SNP) | VAF 28/417 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SPATA31D1 | c.4457C>A p.P1486H | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2
- SPATA46 | c.85C>G p.R29G | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- SPIRE2 | c.1715G>T p.C572F | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPRR2F | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 28/312 reads (9%) | PolyPhen probably damaging (0.93); called by muse, mutect2
- SPTA1 | c.4192C>T p.Q1398* | Nonsense Mutation (SNP) | VAF 42/523 reads (8%) | called by muse, mutect2
- SPTLC2 | c.1300C>G p.L434V | Missense Mutation (SNP) | VAF 52/471 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SREK1IP1 | c.14-1G>T p.X5_splice | Splice Site (SNP) | VAF 21/198 reads (11%) | called by muse, mutect2, varscan2
- SSH1 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- SSH2 | c.3508A>T p.S1170C | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ST6GALNAC5 | c.844A>G p.M282V | Missense Mutation (SNP) | VAF 28/382 reads (7%) | PolyPhen possibly damaging (0.867); called by muse, mutect2
- STAT2 | c.634-1G>T p.X212_splice | Splice Site (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- SUGT1 | c.1049G>T p.R350M (on ENST00000343788 / NM_001130912.3; = p.R318M on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SYNPO2 | c.2723C>G p.P908R | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TACR1 | c.1067C>T p.T356I | Missense Mutation (SNP) | VAF 37/470 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2
- TBL3 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.009); called by muse, varscan2
- TBRG4 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2
- TEAD1 | c.421G>T p.G141W | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2
- TECTA | c.199-1G>A p.X67_splice | Splice Site (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- TEX13C | c.2422C>A p.L808M | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.05); called by muse, mutect2, varscan2
- THRAP3 | c.418A>T p.R140W | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TIAM1 | c.3448A>T p.T1150S | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.29); called by muse, mutect2
- TIGD6 | c.589G>T p.G197* | Nonsense Mutation (SNP) | VAF 13/182 reads (7%) | called by muse, mutect2
- TLK2 | c.2263G>A p.A755T (on ENST00000326270 / NM_001284333.2; = p.A733T on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.956); called by muse, mutect2
- TLN2 | c.3385G>A p.A1129T | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- TMEM106C | c.44G>T p.R15M | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.269); called by muse, mutect2
- TMEM117 | c.1468T>A p.S490T | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2
- TMEM131L | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2
- TMEM132B | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 36/376 reads (10%) | called by muse, mutect2
- TMEM161B | c.98G>C p.C33S | Missense Mutation (SNP) | VAF 27/327 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TMEM174 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 45/601 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- TMEM255A | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- TNIP1 | c.628-1G>T p.X210_splice | Splice Site (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- TNR | c.3383-2A>T p.X1128_splice | Splice Site (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
- TNR | c.2297C>A p.S766Y | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- TNRC6C | c.4891G>T p.G1631C | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- TPR | c.4390G>T p.G1464* | Nonsense Mutation (SNP) | VAF 34/292 reads (12%) | called by muse, varscan2
- TPRA1 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.306); called by muse, mutect2
- TRAV19 | c.101T>A p.V34E | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2
- TRAV24 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRERF1 | c.805T>A p.Y269N | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.86); called by muse, mutect2
- TRIM41 | c.704A>T p.K235M | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRIM67 | c.1361C>A p.S454Y | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
377 further variants in this file (60 protein-altering or splice-affecting, 193 silent, 124 other) are not listed here.
